Surgical pathology report (de-identified scan), TCGA case TCGA-VR-A8EZ, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VR-A8EZ-01A (Primary Tumor).

ICD O-3
Carcinoma, squamous cell
Site: Esophagus, distal
Hud C15.5
807013
9/5 11/24/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Esophagus (Distal third)

1 - "Hepatic artery lymph node":
Uninvolved by neoplasia (0/2).

2 - "Esophagus, gastric fundus, gastric body":
-Invasive squamous cell carcinoma histological grade 2, infiltrating the adventitia;
-maximum dimension of tumor: 7.7 cm;
-maximum depth of infiltration: 1.2 cm;
-angiolymphatic invasion: present;
-perineural invasion: present;
-surgical margins: absence of neoplasia.
-Periesophagics lymph nodes: involved by neoplasia (2/13), with capsular transposition and paracoccidioidomycosis associated.
-Gastric segment uninvolved by neoplasia.
-Perigastric lymph nodes: involved by neoplasia (5/13), with capsular transposition.

3 - "Esophageal margin":
Absence of neoplasia.

4 - "Stomach margin":
Absence of neoplasia.

HBAA Discrepancy		✓
Reviewed Initials: MC		

Source: NCI Genomic Data Commons file 4363ec88-ce10-440f-bb77-cf80bbefdf4d (TCGA-VR-A8EZ.5CD32F0A-88CB-471F-8967-9BDF02ED77A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).